Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012418-09A.1 (aliquot TARGET-15-SJMPAL012418-09A.1-01D) from TARGET case TARGET-15-SJMPAL012418, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,940 days).
Specimen TARGET-15-SJMPAL012418-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b3039a8-d1dc-4290-977e-7ebbbf430410.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012418-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012418-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/733b57a6-f628-448a-9cec-38f8c9d20142

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Frame Shift Ins 3, Silent 2, RNA 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIVEP3 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV56019746; called by muse, mutect2
- KIF2B | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs753464095, COSV52127156; called by muse, mutect2, varscan2
- MSL2 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.525); catalogued as rs1428378462; called by muse, varscan2
- NME8 | c.1645C>G p.P549A | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52257602, COSV99553734; called by muse, mutect2, varscan2
- NME8 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254074; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | catalogued as rs780417788; called by mutect2, varscan2
- WT1 | c.1303+5G>C | Splice Region (SNP) | VAF 60/158 reads (38%) | catalogued as CS115106; called by muse, varscan2
- WT1 | c.1068_1069insACGC p.R357Tfs*17 | Frame Shift Ins (INS) | VAF 58/156 reads (37%) | catalogued as COSV60069248, COSV60072819, COSV60075216, COSV60083033, COSV99070052, COSV99070055; called by mutect2, varscan2
- AKAP4 | c.1878G>T p.M626I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.012); called by muse, mutect2
- ASXL2 | c.2751_2752insCCTG p.S918Pfs*9 | Frame Shift Ins (INS) | VAF 65/111 reads (59%) | called by mutect2, pindel, varscan2
- CD33 | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CRTAP | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CYP2F1 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.686); called by muse, mutect2
- GC | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LDHAL6A | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYO10 | c.4217G>T p.S1406I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2
- STARD9 | c.12162C>A p.S4054R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2
- UEVLD | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- NBAS | c.3846G>A p.Q1282= | Silent (SNP) | VAF 89/195 reads (46%) | called by muse, mutect2, varscan2
- POTEH | c.258C>T p.H86= | Silent (SNP) | VAF 116/492 reads (24%) | catalogued as rs370869918; called by muse, mutect2, varscan2
- HLCS | c.-108G>T | 5'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- MST1L | n.1145C>T | RNA (SNP) | VAF 34/188 reads (18%) | catalogued as rs773653735; called by muse, varscan2
